Somatic mutation profile of tumor specimen C3L-06706-02 (aliquot CPT0422050006) from CPTAC case C3L-06706, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 46.2 years (16,868 days).
Specimen C3L-06706-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 07acba90-0d99-4d80-84ed-0ffc09086107.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-06706-31 (Blood Derived Normal), aliquot CPT0422020005; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2139f653-8133-4e92-b10c-c5bd392e0534

The open-access MAF lists 113 somatic variants for this specimen: 73 protein-altering or splice-affecting, 32 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 63, Silent 32, Nonsense Mutation 5, Intron 5, Frame Shift Del 3, Splice Site 2, 3'UTR 2, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.110C>T p.S37F | Missense Mutation (SNP) | VAF 126/459 reads (27%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913403, COSV62687856, COSV62688281, COSV62689256; ClinVar: pathogenic / likely pathogenic; called by mutect2, varscan2
- MAP2K1 | c.607G>A p.E203K | Missense Mutation (SNP) | VAF 42/290 reads (14%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as rs1057519733, CM083720, COSV61068654; ClinVar: pathogenic; called by mutect2, varscan2
- PIK3CA | c.1625A>T p.E542V | Missense Mutation (SNP) | VAF 48/202 reads (24%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs1057519927, COSV55876800, COSV55881194, COSV55893680; ClinVar: likely pathogenic; called by mutect2, varscan2
- PIK3CA | c.2176G>A p.E726K | Missense Mutation (SNP) | VAF 38/154 reads (25%) | hotspot (GDC flag); SIFT tolerated (0.36); PolyPhen benign (0.396); catalogued as rs867262025, CM126693, COSV55875460; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- AEBP1 | c.80C>T p.T27M | Missense Mutation (SNP) | VAF 96/454 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.874); catalogued as rs1031972849, COSV99788496; called by mutect2, varscan2
- AKAP10 | c.13G>A p.G5R | Missense Mutation (SNP) | VAF 106/426 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.574); catalogued as rs542911618; called by mutect2, varscan2
- AKAP3 | c.389G>A p.R130H | Missense Mutation (SNP) | VAF 92/337 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as rs781428229; called by mutect2, varscan2
- ARL13B | c.76A>G p.M26V | Missense Mutation (SNP) | VAF 58/250 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.19); catalogued as rs746717195; called by mutect2, varscan2
- BCOR | c.4321C>T p.Q1441* (on ENST00000378444 / NM_001123385.2; = p.Q1407* on NM_017745.6) | Nonsense Mutation (SNP) | VAF 214/384 reads (56%) | catalogued as COSV60709606; called by mutect2, varscan2
- CACNA1S | c.853G>A p.V285M | Missense Mutation (SNP) | VAF 115/432 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770679071, COSV62941626; called by mutect2, varscan2
- CCSER1 | c.2295C>A p.D765E | Missense Mutation (SNP) | VAF 72/340 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); catalogued as COSV61418223; called by mutect2, varscan2
- GK5 | c.23C>T p.P8L | Missense Mutation (SNP) | VAF 94/350 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs1420723052; called by mutect2, varscan2
- GRM3 | c.697G>A p.E233K | Missense Mutation (SNP) | VAF 130/516 reads (25%) | SIFT tolerated (1); PolyPhen probably damaging (0.941); catalogued as COSV64475000; called by mutect2, varscan2
- KCNG1 | c.1165G>T p.A389S | Missense Mutation (SNP) | VAF 150/638 reads (24%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.968); catalogued as COSV65369677; called by mutect2, varscan2
- KDM6A | c.3320del p.P1107Lfs*13 | Frame Shift Del (DEL) | VAF 17/169 reads (10%) | catalogued as COSV65045545; called by mutect2, pindel, varscan2
- KLF5 | c.911C>T p.P304L | Missense Mutation (SNP) | VAF 108/477 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs867921927, COSV66614545, COSV66614659; called by mutect2, varscan2
- LLGL2 | c.1688G>A p.R563H | Missense Mutation (SNP) | VAF 145/534 reads (27%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.879); catalogued as rs766268182, COSV51398023; called by mutect2, varscan2
- MMP16 | c.53C>T p.S18L | Missense Mutation (SNP) | VAF 62/326 reads (19%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); catalogued as COSV99073895, COSV99687927; called by mutect2, varscan2
- MVB12B | c.100G>A p.E34K | Missense Mutation (SNP) | VAF 72/404 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.971); catalogued as COSV99068990; called by mutect2, varscan2
- NCAPD3 | c.953G>A p.R318H | Missense Mutation (SNP) | VAF 82/402 reads (20%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs766143479, COSV101596358; called by mutect2, varscan2
- NDUFA7 | c.8C>T p.S3F | Missense Mutation (SNP) | VAF 94/379 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as rs1204773991; called by mutect2, varscan2
- NMRK1 | c.564A>C p.E188D | Missense Mutation (SNP) | VAF 50/334 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as rs748675984; called by mutect2, varscan2
- NXPE4 | c.322C>T p.R108* | Nonsense Mutation (SNP) | VAF 149/558 reads (27%) | catalogued as rs377657848; called by mutect2, varscan2
- PAX1 | c.656G>A p.R219H | Missense Mutation (SNP) | VAF 95/658 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs781301842, COSV68271912, COSV68272092; called by mutect2, varscan2
- PCDHB16 | c.77C>T p.A26V | Missense Mutation (SNP) | VAF 120/472 reads (25%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.023); catalogued as rs782438033; called by mutect2, varscan2
- PRICKLE1 | c.1408G>C p.D470H | Missense Mutation (SNP) | VAF 76/344 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.786); catalogued as COSV58209087; called by mutect2, varscan2
- RNF111 | c.2443G>A p.G815R | Missense Mutation (SNP) | VAF 48/198 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV62084959; called by mutect2, varscan2
- SHC3 | c.43G>A p.V15M | Missense Mutation (SNP) | VAF 226/486 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.546); catalogued as COSV101011838; called by mutect2, varscan2
- SLC25A27 | c.340G>C p.E114Q | Missense Mutation (SNP) | VAF 63/256 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.062); catalogued as COSV99055258; called by mutect2, varscan2
- SLC38A3 | c.430G>A p.A144T | Missense Mutation (SNP) | VAF 118/477 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.392); catalogued as rs1326939718; called by mutect2, varscan2
- SLC9A2 | c.1111G>A p.E371K | Missense Mutation (SNP) | VAF 164/462 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs867313703, COSV52131432, COSV99295912; called by mutect2, varscan2
- SPAG5 | c.2852G>A p.R951Q | Missense Mutation (SNP) | VAF 92/369 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.314); catalogued as rs546549488, COSV56885955, COSV99881681; called by mutect2, varscan2
- SV2C | c.445C>T p.R149C | Missense Mutation (SNP) | VAF 106/434 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs769027251, COSV59228129; called by mutect2, varscan2
- THEGL | c.1096C>T p.P366S | Missense Mutation (SNP) | VAF 46/200 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1048836843, COSV72866453; called by mutect2, varscan2
- TMEM268 | c.736G>A p.E246K | Missense Mutation (SNP) | VAF 334/699 reads (48%) | SIFT tolerated (0.11); PolyPhen benign (0.163); catalogued as COSV99938685, COSV99938851; called by mutect2, varscan2
- TNRC6C | c.4879C>T p.R1627C | Missense Mutation (SNP) | VAF 121/544 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as rs1020151045; called by mutect2, varscan2
- WDFY4 | c.2993C>T p.T998M | Missense Mutation (SNP) | VAF 114/432 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.925); catalogued as rs996278469, COSV57436427; called by mutect2, varscan2
- YTHDC1 | c.1021C>T p.R341* | Nonsense Mutation (SNP) | VAF 39/235 reads (17%) | catalogued as COSV100704747, COSV60009488; called by mutect2, varscan2
- ZNF462 | c.1955G>A p.S652N | Missense Mutation (SNP) | VAF 286/636 reads (45%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.346); catalogued as rs756901264; called by mutect2, varscan2
- ZNF462 | c.4294A>G p.S1432G | Missense Mutation (SNP) | VAF 112/594 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs770940701; called by mutect2, varscan2
- AEBP1 | c.2710-1G>A p.X904_splice | Splice Site (SNP) | VAF 80/362 reads (22%) | called by mutect2, varscan2
- AL592490.1 | c.2674G>T p.A892S | Missense Mutation (SNP) | VAF 69/324 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.265); called by mutect2, varscan2
- AOPEP | c.188C>T p.A63V | Missense Mutation (SNP) | VAF 106/636 reads (17%) | SIFT tolerated (0.45); PolyPhen benign (0.034); called by mutect2, varscan2
- APBB2 | c.1199C>T p.P400L (on ENST00000295974 / NM_001166050.2; = p.P401L on NM_004307.2) | Missense Mutation (SNP) | VAF 74/295 reads (25%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.717); called by mutect2, varscan2
- ATG3 | c.524C>T p.T175I | Missense Mutation (SNP) | VAF 49/212 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.006); called by mutect2, varscan2
- ATRN | c.3782C>G p.T1261S | Missense Mutation (SNP) | VAF 27/232 reads (12%) | SIFT tolerated (0.68); PolyPhen benign (0.019); called by mutect2, varscan2
- B3GLCT | c.596+2_596+5del p.X199_splice | Splice Site (DEL) | VAF 59/207 reads (29%) | called by mutect2, pindel, varscan2
- BIRC6 | c.2234T>A p.L745* | Nonsense Mutation (SNP) | VAF 166/406 reads (41%) | called by mutect2, varscan2
- C10orf71 | c.1686del p.D563Mfs*27 | Frame Shift Del (DEL) | VAF 101/397 reads (25%) | called by mutect2, pindel, varscan2
- CR1L | c.1300T>C p.S434P | Missense Mutation (SNP) | VAF 94/332 reads (28%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.494); called by mutect2, varscan2
- CRISPLD1 | c.1016C>T p.A339V | Missense Mutation (SNP) | VAF 32/175 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.862); called by mutect2, varscan2
- ERLIN1 | c.137C>T p.P46L | Missense Mutation (SNP) | VAF 68/253 reads (27%) | SIFT tolerated (0.38); PolyPhen benign (0.403); called by mutect2, varscan2
- FAM189A1 | c.184G>A p.V62I | Missense Mutation (SNP) | VAF 94/367 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0.023); called by mutect2, varscan2
- FAM219B | c.73G>A p.D25N | Missense Mutation (SNP) | VAF 134/520 reads (26%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.035); called by mutect2, varscan2
- INTS7 | c.2860C>T p.Q954* | Nonsense Mutation (SNP) | VAF 104/426 reads (24%) | called by mutect2, varscan2
- KIRREL3 | c.185G>A p.G62E | Missense Mutation (SNP) | VAF 118/501 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- LRRC45 | c.853G>A p.G285R | Missense Mutation (SNP) | VAF 86/322 reads (27%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.708); called by mutect2, varscan2
- NAT16 | c.421C>T p.R141C | Missense Mutation (SNP) | VAF 179/584 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); called by mutect2, varscan2
- NR0B2 | c.94G>A p.V32I | Missense Mutation (SNP) | VAF 136/566 reads (24%) | SIFT tolerated (0.44); PolyPhen benign (0.003); called by mutect2, varscan2
- NRCAM | c.3311G>A p.G1104D | Missense Mutation (SNP) | VAF 32/160 reads (20%) | SIFT tolerated (0.51); PolyPhen benign (0.009); called by mutect2, varscan2
- NXPE1 | c.788G>A p.R263K (on ENST00000424269; = p.R121K on NM_152315.5) | Missense Mutation (SNP) | VAF 48/322 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.006); called by mutect2, varscan2
- OBSCN | c.4774G>C p.V1592L | Missense Mutation (SNP) | VAF 94/440 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.345); called by mutect2, varscan2
- PEG3 | c.4369G>A p.G1457S | Missense Mutation (SNP) | VAF 98/724 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by mutect2, varscan2
- PHACTR1 | c.197A>C p.K66T | Missense Mutation (SNP) | VAF 78/316 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.665); called by mutect2, varscan2
- PYGO2 | c.926C>T p.A309V | Missense Mutation (SNP) | VAF 176/657 reads (27%) | SIFT tolerated (0.29); PolyPhen benign (0.102); called by mutect2, varscan2
- ROBO3 | c.2083C>T p.P695S | Missense Mutation (SNP) | VAF 61/314 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.388); called by mutect2, varscan2
- SLC25A13 | c.1556G>A p.S519N | Missense Mutation (SNP) | VAF 96/372 reads (26%) | SIFT tolerated (0.28); PolyPhen benign (0.023); called by mutect2, varscan2
- SRRM3 | c.1354G>A p.G452S | Missense Mutation (SNP) | VAF 68/210 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.15); called by mutect2, varscan2
- STXBP4 | c.1291C>T p.L431F | Missense Mutation (SNP) | VAF 38/156 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by mutect2, varscan2
- TGFBI | c.473C>T p.S158F | Missense Mutation (SNP) | VAF 78/311 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); called by mutect2, varscan2
- TTN | c.64514C>A p.P21505Q (on ENST00000591111; = p.P14081Q on NM_003319.4) | Missense Mutation (SNP) | VAF 110/392 reads (28%) | PolyPhen probably damaging (0.999); called by mutect2, varscan2
- ZNF10 | c.281_285del p.K94Ifs*9 | Frame Shift Del (DEL) | VAF 29/189 reads (15%) | called by pindel, varscan2
- ZNF560 | c.1348C>T p.H450Y | Missense Mutation (SNP) | VAF 82/353 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by mutect2, varscan2
- ABCA2 | c.2034C>T p.P678= (on ENST00000614293; = p.P648= on NM_001606.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 352/691 reads (51%) | called by mutect2, varscan2
- ABCA3 | c.3675C>T p.F1225= | Silent (SNP) | VAF 76/302 reads (25%) | called by mutect2, varscan2
- AFF3 | c.1836C>T p.D612= | Silent (SNP) | VAF 133/611 reads (22%) | called by mutect2, varscan2
- ARHGEF37 | c.1392G>A p.L464= | Silent (SNP) | VAF 99/412 reads (24%) | catalogued as COSV61368027; called by mutect2, varscan2
- ASTL | c.939G>A p.L313= | Silent (SNP) | VAF 126/700 reads (18%) | called by mutect2, varscan2
- C12orf45 | c.96G>T p.A32= | Silent (SNP) | VAF 82/332 reads (25%) | called by mutect2, varscan2
- CACNB2 | c.1260C>T p.N420= (on ENST00000324631 / NM_201596.3; = p.N365= on NM_000724.4) | Silent (SNP) | VAF 54/243 reads (22%) | catalogued as rs931370978; called by mutect2, varscan2
- CDH3 | c.558C>T p.H186= | Silent (SNP) | VAF 77/314 reads (25%) | catalogued as rs775627086, COSV50560383; called by mutect2, varscan2
- CORO1A | c.1080G>A p.Q360= | Silent (SNP) | VAF 100/404 reads (25%) | catalogued as rs753747500; called by mutect2, varscan2
- DENND5A | c.939C>T p.L313= | Silent (SNP) | VAF 56/178 reads (31%) | catalogued as rs369277847; called by mutect2, varscan2
- FAM47A | c.306C>T p.A102= | Silent (SNP) | VAF 122/239 reads (51%) | called by mutect2, varscan2
- FASLG | c.633C>T p.V211= | Silent (SNP) | VAF 120/462 reads (26%) | called by mutect2, varscan2
- FREM2 | c.7317A>G p.A2439= | Silent (SNP) | VAF 100/439 reads (23%) | called by mutect2, varscan2
- GAA | c.1740C>G p.A580= | Silent (SNP) | VAF 58/266 reads (22%) | called by mutect2, varscan2
- GIPC3 | c.3435C>T p.A1145= | Silent (SNP) | VAF 68/314 reads (22%) | called by mutect2, varscan2
- GSTT2B | c.513G>A p.E171= | Silent (SNP) | VAF 28/100 reads (28%) | called by mutect2, varscan2
- IGF2R | c.4560C>T p.N1520= | Silent (SNP) | VAF 48/256 reads (19%) | catalogued as rs1244303508; called by mutect2, varscan2
- KIAA0895L | c.177C>G p.P59= | Silent (SNP) | VAF 134/534 reads (25%) | called by mutect2, varscan2
- MYBBP1A | c.2607G>A p.Q869= | Silent (SNP) | VAF 116/429 reads (27%) | called by mutect2, varscan2
- NAV1 | c.718C>T p.L240= | Silent (SNP) | VAF 98/362 reads (27%) | called by mutect2, varscan2
- NOXO1 | c.319C>T p.L107= (on ENST00000397280 / NM_172168.3; = p.L101= on NM_144603.4) | Silent (SNP) | VAF 138/541 reads (26%) | called by mutect2, varscan2
- PCDHB11 | c.1206G>A p.T402= | Silent (SNP) | VAF 98/356 reads (28%) | called by mutect2, varscan2
- PRRX2 | c.39G>T p.P13= | Silent (SNP) | VAF 84/402 reads (21%) | called by mutect2, varscan2
- ROPN1L | c.447C>T p.C149= | Silent (SNP) | VAF 76/284 reads (27%) | catalogued as rs753462592, COSV56873528; called by mutect2, varscan2
- SARM1 | c.894G>A p.P298= | Silent (SNP) | VAF 152/555 reads (27%) | catalogued as rs149305024; called by mutect2, varscan2
- SLC13A3 | c.21G>A p.A7= | Silent (SNP) | VAF 91/489 reads (19%) | catalogued as rs761335081; called by mutect2, varscan2
- SLC25A4 | c.285C>T p.Y95= | Silent (SNP) | VAF 94/453 reads (21%) | called by mutect2, varscan2
- SORBS3 | c.1608C>T p.A536= | Silent (SNP) | VAF 200/620 reads (32%) | catalogued as rs780876574, COSV99531027; called by mutect2, varscan2
- TOP3B | c.2001T>C p.P667= | Silent (SNP) | VAF 132/471 reads (28%) | called by mutect2, varscan2
- TTN | c.42216T>C p.S14072= (on ENST00000591111; = p.S6648= on NM_003319.4) | Silent (SNP) | VAF 178/472 reads (38%) | called by mutect2, varscan2
- ZNF703 | c.759G>A p.P253= | Silent (SNP) | VAF 160/568 reads (28%) | called by mutect2, varscan2
- ZNF722P | c.192G>A p.L64= | Silent (SNP) | VAF 35/182 reads (19%) | called by mutect2, varscan2
- APBB1 | c.722-928G>A | Intron (SNP) | VAF 104/438 reads (24%) | called by mutect2, varscan2
- BCL2L10 | c.*1G>T | 3'UTR (SNP) | VAF 63/278 reads (23%) | catalogued as COSV53064803; called by mutect2, varscan2
- HHLA2 | c.-71G>A | 5'UTR (SNP) | VAF 74/292 reads (25%) | called by mutect2, varscan2
- IFNL4 | c.223+82C>T | Intron (SNP) | VAF 506/970 reads (52%) | called by mutect2, varscan2
- MLIP | c.613-11978C>T | Intron (SNP) | VAF 96/440 reads (22%) | called by mutect2, varscan2
- PSMB10 | c.558+104G>A | Intron (SNP) | VAF 128/403 reads (32%) | called by mutect2, varscan2
- RBM44 | c.-98-1870C>T | Intron (SNP) | VAF 74/414 reads (18%) | called by mutect2, varscan2
- TMEM250 | c.*101G>A | 3'UTR (SNP) | VAF 101/636 reads (16%) | called by mutect2, varscan2
